Gene-level copy-number profile of tumor specimen HCM-BROD-0962-C16-06A from HCMI case HCM-BROD-0962-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Tumor grade: G3; Age at diagnosis: 62.3 years (22,747 days).
Specimen HCM-BROD-0962-C16-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ece66e1a-ab1c-462b-bca2-1534f17f4f1f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0962-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/7ef64967-be49-47b1-a5fc-d98f9756ce4b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 8,555; copy number 2: 48,513; copy number 3: 461; copy number 4: 500; copy number 5: 70; copy number 6: 37; copy number 7: 18; copy number 8: 5; copy number 9: 53; copy number 11: 22; copy number 12: 30; copy number 13: 9; copy number 14: 5; copy number 15: 13; copy number 16: 2; copy number 18: 6; copy number 19: 19; copy number 20: 24; copy number 21: 4; copy number 22: 10; copy number 26: 33.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:190,064,502–190,092,279, 10 genes: DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 360 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,315,040–2,391,707, 4 genes, copy number 5 (within-gene range 2–5): AL590822.3, MORN1, AL589739.1, AL513477.1.
- chr12:58,872,149–59,450,772, 8 genes, copy number 7: LRIG3, AC068305.2, RPS6P22, AC068305.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P.
- chr12:65,824,460–71,927,248, 125 genes, copy number 5–26 (within-gene range 3–26) (broad region; genes not listed).
- chr20:41,402,083–41,685,091, 5 genes, copy number 8: CHD6, AL031667.2, AL031667.3, RPL12P11, RNU6-1018P.
- chr20:47,209,214–47,656,877, 10 genes, copy number 19 (within-gene range 1–19): ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3, AL034418.1.
- chr20:50,040,716–50,321,342, 12 genes, copy number 6: TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271.
- chr20:51,782,331–53,668,758, 29 genes, copy number 14–20: SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P.
- chr20:56,205,052–56,299,160, 4 genes, copy number 21: RNA5SP487, MC3R, AL139824.2, AL139824.1.
- chr20:57,599,695–60,083,872, 57 genes, copy number 7–20: AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, PIEZO1P1, AL389889.1, PHACTR3, PHACTR3-AS1, RNU7-141P, SYCP2, FAM217B, PPP1R3D, CDH26, C20orf197, AL132822.1.
- chr20:60,564,562–62,814,000, 56 genes, copy number 6–26: MIR548AG2, AL117372.1, AL139348.1, AL121910.1, LINC01718, CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2, TAF4, MIR1257, AL137077.1, MIR3195, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659, MRGBP, OGFR-AS1, OGFR.
- chr22:20,299,760–21,070,097, 50 genes, copy number 5: AC007663.1, DGCR6L, AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5, USP41, ZNF74, RNU6-225P, SCARF2, AC007731.4, KLHL22, AC007731.1, RNY1P9, Y_RNA, RN7SL812P, KRT18P5, MED15, AC007731.3, CCDC74BP1, SMPD4P1, IGLL4P, SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP.

Autosomal genes at a single copy (total copy number 1): 6,539. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
